Surgical pathology report (de-identified scan), TCGA case TCGA-CG-4438, project TCGA-STAD (Stomach Adenocarcinoma), tissue source site Indivumed, specimen TCGA-CG-4438-01A (Primary Tumor).

■
Diagnosis/diagnoses:

Total gastrectomy preparation with the inclusion of an extensive, widespread, ulcerated, poorly differentiated adenocarcinoma (intestinal type) with a maximum diameter of 9 cm and extending as far as the pylorus with infiltration of the perigastric fatty tissue and circumscribed penetration of the overlying serosa. Thirteen regional lymph node metastases. Tumor-free oral resection margin covered with unremarkable squamous epithelium and also tumor-free aboral resection margin covered with characteristic duodenal mucosa. Tumor-free omentum.

Tumor stage: pT3 pN2 (14/58) pMX; ■

Source: NCI Genomic Data Commons file ce4f90fd-2b99-48fc-bd3e-1b3145dbe672 (TCGA-CG-4438.CDF1FD9E-640D-478B-AF18-E4084B97940B.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).